Gene-level copy-number profile of tumor specimen ALCH-B2V6-TTP1-A from ALCHEMIST case ALCH-B2V6, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 80.2 years (29,295 days).
Specimen ALCH-B2V6-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2e49fa0e-22c1-460d-b3f1-09495c073604.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2V6-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,292 have no estimate.
https://portal.gdc.cancer.gov/files/d5a3256b-2524-493c-ae57-d8908e7a4710

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 7; copy number 2: 82; copy number 3: 5,439; copy number 4: 36,392; copy number 5: 11,921; copy number 6: 2,632; copy number 7: 1,691; copy number 8: 106; copy number 9: 40; copy number 10: 12; copy number 11: 3; copy number 12: 1; copy number 13: 2; copy number 14: 2; copy number 24: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 56 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:149,229,356–149,433,274, 8 genes, copy number 9–10: CPHL1P, AC093001.1, TM4SF18, AC073522.1, TM4SF1, TM4SF1-AS1, AC108751.4, AC108751.2.
- chr3:152,243,828–152,496,813, 5 genes, copy number 9–10: MBNL1, MBNL1-AS1, TMEM14EP, Y_RNA, AC026347.1.
- chr3:169,083,499–169,663,775, 4 genes, copy number 9: MECOM, MECOM-AS1, RPL22P1, AC007849.1.
- chr3:169,773,396–169,869,935, 7 genes, copy number 9: MYNN, AC078795.1, LRRC34, AC078795.3, AC078795.2, LRRIQ4, LRRC31.
- chr3:170,037,995–170,085,392, 3 genes, copy number 9: GPR160, RNU4-38P, KMT5AP3.
- chr5:50,662,859–50,663,266, 1 gene, copy number 11: AC112187.3.
- chr6:46,997,708–47,042,350, 1 gene, copy number 9: ADGRF1.
- chr8:134,832,747–134,834,482, 1 gene, copy number 9: AC083843.1.
- chr8:142,750,150–142,752,532, 1 gene, copy number 14: LYPD2.
- chr8:143,541,648–143,549,729, 3 genes, copy number 9: AC067930.9, AC067930.3, RN7SKP175.
- chr11:66,002,228–66,004,149, 1 gene, copy number 10: BANF1.
- chr11:67,435,510–67,443,821, 2 genes, copy number 9: PTPRCAP, CORO1B.
- chr11:67,491,768–67,508,649, 2 genes, copy number 9: PITPNM1, CDK2AP2.
- chr11:67,602,880–67,606,706, 2 genes, copy number 9: C11orf72, AP003385.3.
- chr13:44,234,118–44,256,596, 1 gene, copy number 10 (within-gene range 8–10): AL589745.1.
- chr15:28,575,019–28,579,400, 1 gene, copy number 24: HERC2P11.
- chr15:70,503,907–70,505,928, 1 gene, copy number 10: LINC02205.
- chr15:84,633,874–84,634,635, 1 gene, copy number 10 (within-gene range 7–10): EGLN1P1.
- chr16:991,151–1,000,926, 1 gene, copy number 14: AC009041.1.
- chr16:1,088,226–1,105,461, 2 genes, copy number 9: C1QTNF8, AL031713.1.
- chr20:3,227,417–3,239,559, 1 gene, copy number 9: SLC4A11.
- chr20:53,875,252–53,875,557, 1 gene, copy number 10: SUMO1P1.
- chr20:62,804,835–62,814,000, 1 gene, copy number 12 (within-gene range 6–12): OGFR.
- chr20:63,272,785–63,334,851, 3 genes, copy number 10–11: ARFGAP1, MIR4326, COL20A1.
- chr22:38,231,320–38,232,248, 2 genes, copy number 13 (within-gene range 4–13): AL020993.1, RN7SL704P.

Autosomal genes at a single copy (total copy number 1): 7. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
